EXCEPTIONAL_RESPONDERS case ER-ADBU — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fce3719e-429c-4150-945b-491aaffcf7a4

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1962; Vital status: Dead; Days to death: 5,527 days (15.1 years); Year of death: 2016.

Diagnoses (1)
1. Gastrointestinal stromal tumor, malignant: ICD-O-3 morphology code: 8936/3; Tissue or organ of origin: Overlapping lesion of ill-defined sites; Site of resection or biopsy: Overlapping lesion of ill-defined sites; Classification of tumor: primary; Age at diagnosis: 38.8 years (14,162 days); Year of diagnosis: 2001; AJCC staging edition: 7th; AJCC clinical stage: Stage IVB; Prior malignancy: no; Days to last follow up: 3,346 days (9.2 years); Days to best overall response: 222 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Imatinib; Days to treatment start: 88 days; Days to treatment end: 2,334 days (6.4 years).

Follow-up (1 entry)
- Days to follow up: 3,346 days (9.2 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 3,346 days (9.2 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ADBU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Preservation method: FFPE.
  Slide ER-ADBU-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ADBU-TTR1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Preservation method: FFPE.
